Somatic mutation profile of tumor specimen TARGET-20-PARPBF-09A (aliquot TARGET-20-PARPBF-09A-02D) from TARGET case TARGET-20-PARPBF, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.6 years (6,424 days).
Specimen TARGET-20-PARPBF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55705dbb-9432-4d8b-a49b-efe3c9870d51.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARPBF-14A (Bone Marrow Normal), aliquot TARGET-20-PARPBF-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/283b6fb4-d24e-4231-a7a9-691519357df9

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 47/182 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 24/184 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- COL12A1 | c.8852G>T p.G2951V | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100485971; called by muse, mutect2, varscan2
- TRRAP | c.7307C>T p.T2436M (on ENST00000359863 / NM_001244580.1; = p.T2418M on NM_003496.3) | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs931406299; called by muse, mutect2, varscan2
- BCOR | c.4459_4460insCC p.I1487Tfs*5 (on ENST00000378444 / NM_001123385.2; = p.I1453Tfs*5 on NM_017745.6) | Frame Shift Ins (INS) | VAF 55/85 reads (65%) | called by mutect2, pindel, varscan2
